Somatic mutation profile of tumor specimen TCGA-F9-A97G-01A (aliquot TCGA-F9-A97G-01A-11D-A382-10) from TCGA case TCGA-F9-A97G, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 79.8 years (29,156 days).
Specimen TCGA-F9-A97G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29d84ca6-3772-4bee-a0b2-31c276494fe7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F9-A97G-10A (Blood Derived Normal), aliquot TCGA-F9-A97G-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b59223a9-7fa8-471a-a726-f59bb75838db

The open-access MAF lists 71 somatic variants for this specimen: 57 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 42, Silent 14, Frame Shift Del 6, Splice Site 4, In Frame Del 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 27/121 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685508, COSV61687178; called by muse, mutect2, varscan2
- AP1M2 | c.327C>G p.I109M | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV51569672, COSV99140947; called by muse, mutect2, varscan2
- ATP11A | c.874T>A p.S292T | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs1349150330, COSV99369487; called by muse, mutect2, varscan2
- ATRNL1 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs782462907, COSV100372180; called by muse, mutect2, varscan2
- C16orf91 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100113741; called by muse, mutect2, varscan2
- CENPE | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99478681; called by muse, mutect2, varscan2
- CFAP91 | c.926A>C p.E309A | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99847374; called by muse, mutect2, varscan2
- CNOT11 | c.1172T>C p.I391T | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99179348; called by muse, mutect2, varscan2
- CNOT9 | c.422G>C p.G141A | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99813791; called by muse, mutect2, varscan2
- ELP1 | c.1918A>T p.N640Y | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101010448; called by muse, mutect2, varscan2
- FBN2 | c.6153del p.S2051Rfs*7 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as COSV52516420; called by mutect2, pindel, varscan2
- FLNB | c.3104C>T p.S1035L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.028); catalogued as rs752525780, COSV99914132; called by muse, mutect2, varscan2
- FOXN3 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as rs763235859, COSV99726969; called by muse, mutect2, varscan2
- GPR37 | c.1339T>A p.F447I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100391077; called by muse, mutect2, varscan2
- HAPLN1 | c.101-2A>G p.X34_splice | Splice Site (SNP) | VAF 39/226 reads (17%) | catalogued as COSV99164609; called by muse, mutect2, varscan2
- HOGA1 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101035560; called by muse, mutect2, varscan2
- HSPG2 | c.9578C>T p.T3193I | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as COSV101013520; called by muse, mutect2, varscan2
- KCNC4 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 87/378 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV100873667; called by muse, mutect2, varscan2
- KCNQ4 | c.834+2T>G p.X278_splice | Splice Site (SNP) | VAF 18/95 reads (19%) | catalogued as COSV100714388; called by muse, mutect2, varscan2
- LHX4 | c.511A>G p.T171A | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); catalogued as COSV55375887; called by muse, mutect2, varscan2
- LHX4 | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV99761770; called by muse, mutect2, varscan2
- LNX1 | c.1070G>T p.R357L (on ENST00000263925 / NM_001126328.3; = p.R261L on NM_032622.2) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55791219, COSV99820336; called by muse, mutect2, varscan2
- LRP1B | c.8192A>C p.K2731T | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV101259038; called by muse, mutect2, varscan2
- LRRC59 | c.133G>C p.D45H | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773759187, COSV99869716; called by muse, mutect2, varscan2
- MORN5 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV65648961; called by muse, mutect2, varscan2
- MROH5 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV71300565; called by muse, mutect2, varscan2
- MRPL3 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as rs766569622, COSV99394953; called by muse, mutect2, varscan2
- PCSK1 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100227215; called by muse, mutect2, varscan2
- PDE6B | c.1312A>C p.M438L | Missense Mutation (SNP) | VAF 69/400 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV99728114; called by muse, mutect2, varscan2
- PLA2G4F | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV51826395; called by muse, mutect2, varscan2
- PLCH1 | c.4108T>A p.S1370T (on ENST00000340059 / NM_001130960.2; = p.S1362T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.104); catalogued as COSV100397808; called by muse, mutect2, varscan2
- PLD5 | c.308dup p.N103Kfs*5 (on ENST00000442594; = p.N41Kfs*5 on NM_001195811.1 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/77 reads (21%) | catalogued as rs1558485246; called by mutect2, varscan2
- PPP1R16A | c.1246G>T p.G416W | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV99477762; called by muse, mutect2, varscan2
- PRDM10 | c.2030G>C p.C677S | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV100456919; called by muse, mutect2, varscan2
- PRNP | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV101057343; called by muse, mutect2, varscan2
- RHPN2 | c.1751A>G p.D584G | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV99578048; called by muse, mutect2, varscan2
- SEMA5B | c.1831G>A p.G611S | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99532736; called by muse, mutect2, varscan2
- SHANK3 | c.3115T>C p.S1039P | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV99437548; called by muse, mutect2, varscan2
- SRRM1 | c.22-2A>G p.X8_splice | Splice Site (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100104978; called by muse, mutect2, varscan2
- ST8SIA3 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 26/94 reads (28%) | PolyPhen benign (0.113); catalogued as COSV100129626; called by muse, mutect2, varscan2
- SYVN1 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV99589218; called by muse, mutect2, varscan2
- TAS2R50 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.708); catalogued as COSV101115283; called by muse, mutect2, varscan2
- TBX15 | c.1595C>T p.P532L (on ENST00000369429 / NM_001330677.2; = p.P426L on NM_152380.3) | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99254531; called by muse, mutect2, varscan2
- THBS1 | c.1485G>T p.W495C | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99528227; called by muse, mutect2, varscan2
- UBE3A | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs765813410, COSV51667064; called by muse, mutect2, varscan2
- ZFR2 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs758661848, COSV99507682; called by muse, mutect2, varscan2
- CHTF18 | c.2645_2647del p.I882_G883delinsR | In Frame Del (DEL) | VAF 15/108 reads (14%) | called by mutect2, pindel, varscan2
- COL4A6 | c.517del p.D173Ifs*23 | Frame Shift Del (DEL) | VAF 237/645 reads (37%) | called by mutect2, pindel, varscan2
- HECW1 | c.3804_3810del p.M1268Ifs*65 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | called by mutect2, pindel, varscan2
- HSD11B1 | c.394_396del p.D132del | In Frame Del (DEL) | VAF 30/158 reads (19%) | called by pindel, varscan2
- IGKV1-5 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- MTRR | c.1889_1902del p.T630Ifs*55 (on ENST00000264668; = p.T603Ifs*55 on NM_002454.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 54/262 reads (21%) | called by mutect2, pindel, varscan2
- PIK3R3 | c.335del p.L112* | Frame Shift Del (DEL) | VAF 35/181 reads (19%) | called by mutect2, pindel, varscan2
- PPP2R3C | c.1218_1225del p.S407Gfs*6 | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- SBF2 | c.1297-4_1298del p.X433_splice | Splice Site (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- SLC26A1 | c.1968_1970del p.I656_L657delinsM | In Frame Del (DEL) | VAF 37/159 reads (23%) | called by mutect2, pindel, varscan2
- TTF1 | c.584_601del p.E195_S200del | In Frame Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- CEP290 | c.5508A>C p.I1836= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV100469406; called by muse, varscan2
- DLGAP3 | c.1947C>T p.N649= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV99333013; called by muse, mutect2, varscan2
- GUSB | c.837A>G p.Q279= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs750430817, COSV59222495; called by muse, mutect2, varscan2
- LRP2 | c.1686A>T p.V562= | Silent (SNP) | VAF 70/305 reads (23%) | catalogued as COSV99789675; called by muse, mutect2, varscan2
- LRTOMT | c.115C>A p.R39= | Silent (SNP) | VAF 62/283 reads (22%) | catalogued as COSV99194436; called by muse, varscan2
- PHC3 | c.2310T>A p.I770= (on ENST00000494943 / NM_001308116.2; = p.I782= on NM_024947.4) | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as rs532102572, COSV101520182, COSV71948776; called by muse, mutect2, varscan2
- PLEKHA7 | c.2949G>T p.S983= | Silent (SNP) | VAF 28/154 reads (18%) | catalogued as rs768979909, COSV100261977; called by muse, mutect2, varscan2
- PLEKHG3 | c.1827C>G p.L609= (on ENST00000394691; = p.L665= on NM_001308147.2) | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV55979526, COSV99906910; called by muse, mutect2, varscan2
- SLC16A2 | c.264C>T p.T88= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as rs1283259041, COSV99330934; called by muse, mutect2, varscan2
- SYNM | c.4344A>G p.L1448= | Silent (SNP) | VAF 57/255 reads (22%) | catalogued as COSV100019117; called by muse, mutect2, varscan2
- TFPT | c.636G>A p.P212= | Silent (SNP) | VAF 39/175 reads (22%) | catalogued as rs193019766, COSV100338268; called by muse, mutect2, varscan2
- TMEM132E | c.1038G>A p.R346= (on ENST00000321639; = p.R436= on NM_001304438.2) | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs1052615102, COSV100396641; called by muse, varscan2
- XYLT2 | c.1476G>T p.R492= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV99191041; called by muse, mutect2, varscan2
- YWHAG | c.528T>A p.A176= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as COSV100297398; called by muse, mutect2, varscan2
